Surgical pathology report (de-identified scan), TCGA case TCGA-D9-A1JW, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D9-A1JW-06A (Metastatic).

ICB-0-3
Melanoma Nos 8720/3
Site: lymph nodes, cervical C770
page 1 / 1
3/11/11

Department of Cancer Pathology

copy No. 1

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.

Patient: XXX

PESEL: XXX

Age:

Gender: M

Material: Lesion resection – cervical lymph nodes

Unit in charge:

Physician in charge:

Material collected on:

Material received on: 1

Expected time of examination: 5 working days

Clinical diagnosis: Cervical tumour, right side

Examination performed on:

Macroscopic description:

Surgical specimen sized 4.5 x 3 x 1.7 cm, in the cross section: lymph node sized 1 x 1.4 x 2.5 cm surrounded by fat tissue.

Examination result:

Metastasis melanomatis maligni in lymphonodo NO I/I plus a fragment of salivary gland texture.

Metastases of malignant melanoma in lymph node No I/I plus a fragment of salivary gland texture.

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 22098274-067b-4086-a3a3-cc66d2a59ed9 (TCGA-D9-A1JW.E532715E-CC41-4AFF-A783-BB3A02E53309.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).